Somatic mutation profile of tumor specimen TCGA-GR-A4D5-01A (aliquot TCGA-GR-A4D5-01A-11D-A31X-10) from TCGA case TCGA-GR-A4D5, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 46.6 years (17,023 days).
Specimen TCGA-GR-A4D5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4861108c-3a8f-4b97-8b3a-c39c07557d7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GR-A4D5-10A (Blood Derived Normal), aliquot TCGA-GR-A4D5-10A-01D-A31X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c909e90-9cb0-423e-9745-178c6f27a6f8

The open-access MAF lists 44 somatic variants for this specimen: 30 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 28, Silent 14, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MSN | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1057519074, COSV100814276; ClinVar: pathogenic; called by muse, mutect2
- ADRA2B | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV101337381; called by muse, mutect2
- AKR1C4 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV54125361; called by muse, mutect2
- AMOT | c.1877G>A p.R626H (on ENST00000371959 / NM_001113490.1; = p.R217H on NM_133265.3) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150900068, COSV100495398; called by muse, mutect2
- BMP2 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.414); catalogued as COSV101122108; called by muse, mutect2
- CAPN12 | c.1372G>C p.E458Q | Missense Mutation (SNP) | VAF 24/303 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV99400576; called by muse, mutect2
- CPZ | c.947C>T p.A316V (on ENST00000360986 / NM_001014447.3; = p.A305V on NM_003652.3) | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs983032914, COSV100249145; called by muse, mutect2, varscan2
- CSMD3 | c.9884G>T p.G3295V (on ENST00000297405 / NM_001363185.1; = p.G3126V on NM_052900.3) | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52289645; called by muse, mutect2
- CXCR4 | c.11T>G p.I4S | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV99603303; called by muse, mutect2
- CXXC1 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99496858; called by muse, mutect2
- DNTTIP2 | c.1582A>G p.S528G | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV63283516; called by muse, mutect2
- FLNC | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as rs966097091, COSV100368490, COSV57952945; called by muse, mutect2
- HLA-DMB | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV66870829; called by muse, mutect2
- KDR | c.2046A>C p.E682D | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.95); PolyPhen benign (0.216); catalogued as COSV99818313; called by muse, mutect2
- NRXN1 | c.1948G>A p.D650N | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.799); catalogued as rs202137841, COSV100456275; called by muse, mutect2, varscan2
- PAPPA | c.2176G>A p.A726T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as rs771450068, COSV100074870; called by muse, mutect2, varscan2
- PCDHA4 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs1562206749, COSV63540728, COSV63544178; called by muse, mutect2
- PCDHAC1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201932518; called by muse, mutect2
- PHLDB1 | c.3973C>T p.R1325C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.139); catalogued as rs149980232, COSV99874673; called by muse, mutect2, varscan2
- PIK3C2G | c.841C>G p.Q281E | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.036); catalogued as COSV99853181, COSV99854455; called by muse, mutect2, varscan2
- POLR2E | c.545A>G p.Y182C | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99297670; called by muse, mutect2, varscan2
- PRELID3A | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1227891219, COSV100426975; called by muse, mutect2
- RAB36 | c.438T>G p.N146K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.101); catalogued as COSV99572296; called by muse, mutect2, varscan2
- SMARCA2 | c.2253G>A p.M751I | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100571419, COSV61806985; called by muse, mutect2, varscan2
- TIGD2 | c.613A>G p.S205G | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs1289284702, COSV100392432; called by muse, mutect2
- TLN1 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV100148057; called by muse, mutect2, varscan2
- TMEM30A | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 16/266 reads (6%) | catalogued as rs772644735, COSV57874607; called by muse, mutect2
- TMSB4X | c.100+1G>C p.X34_splice | Splice Site (SNP) | VAF 43/323 reads (13%) | catalogued as COSV101020357; called by muse, mutect2, varscan2
- ZNF578 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV101405094; called by muse, mutect2, varscan2
- MOCS3 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); called by muse, mutect2
- CACNA1S | c.4371C>T p.S1457= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs767347290, COSV100755218; called by mutect2, varscan2
- CHD5 | c.2586C>A p.V862= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV99314470; called by muse, mutect2
- CTSE | c.1008C>T p.P336= (on ENST00000360218; = p.P331= on NM_001910.4) | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as COSV100733652, COSV100733697; called by muse, mutect2
- EFHC1 | c.1458C>G p.G486= | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as COSV100932110; called by muse, mutect2
- H2AC6 | c.252G>A p.L84= | Silent (SNP) | VAF 10/175 reads (6%) | catalogued as COSV100019758, COSV58417813; called by muse, mutect2
- IGLC2 | c.252C>T p.S84= | Silent (SNP) | VAF 21/371 reads (6%) | called by muse, mutect2
- KCNC2 | c.360C>T p.T120= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as COSV100129516; called by muse, mutect2
- OR5T2 | c.709C>T p.L237= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as rs756522716; called by muse, mutect2
- OR9Q2 | c.264C>T p.H88= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs761516412, COSV100285496; called by muse, mutect2, varscan2
- PCDHA12 | c.2133G>C p.L711= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV99167838; called by muse, mutect2, varscan2
- PTPRG | c.1839C>T p.H613= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as rs150936656; called by muse, mutect2, varscan2
- SMPD1 | c.585C>T p.A195= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV100192944; called by muse, mutect2, varscan2
- TCTN1 | c.489C>T p.S163= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as COSV66540966; called by muse, mutect2
- TRPM3 | c.582C>T p.N194= (on ENST00000357533 / NM_001366142.2; = p.N39= on NM_020952.6) | Silent (SNP) | VAF 13/117 reads (11%) | catalogued as COSV62475328; called by muse, mutect2, varscan2
